Somatic mutation profile of tumor specimen BA2246D (aliquot aq-BA2246D) from BEATAML1.0 case 2399, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.7 years (14,152 days).
Specimen BA2246D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9482bade-3edf-4e04-bb33-0657cf61ee7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2513D (Solid Tissue Normal), aliquot aq-BA2513D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db8fb1ee-1998-4e2c-8d70-84424b0282bd

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 43/152 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF10L | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1013769138, COSV51433455; called by muse, mutect2
- CACNA1G | c.89del p.G30Afs*35 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs1425320185; called by pindel, varscan2
- COL19A1 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs183001892, COSV59579330; called by muse, mutect2, varscan2
- NBEAL2 | c.3868C>T p.R1290W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1330626921, COSV52756771; called by muse, mutect2
- SACS | c.10720A>G p.N3574D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1274951632; called by muse, mutect2, varscan2
- ADRA1A | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ARHGAP40 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, varscan2
- CACNA1B | c.1458G>C p.W486C | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IKZF1 | c.966_967insT p.G323Wfs*166 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- ITGB1BP2 | c.942G>C p.R314S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD20 | c.30C>G p.D10E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D10C | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- ZBTB44 | c.1686+1G>C p.X562_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- CFAP43 | c.3273G>A p.P1091= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs151017050; called by muse, mutect2, varscan2
- GPR119 | c.387G>T p.L129= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- RAB11B | c.324G>A p.E108= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.62-21C>A | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs993358751, COSV99772349; called by muse, mutect2
- CILK1 | c.*50C>T | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- LMO3 | c.-9+28C>T | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
